Surgical pathology report (de-identified scan), TCGA case TCGA-06-0237, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0237-01A (Primary Tumor).

[page 1 of 2]
TC6A-06-0237

Surgical Pathology Report

=====

CLINICAL HISTORY

[REDACTED] with recent onset seizure has a right frontal meningioma and a right temporal intra axial enhancing lesion.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain tumor

B: Brain tumor

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right temporal, excisional biopsies: Glioblastoma.

See Comment.

COMMENT

In parts A and B there is an astrocytic neoplastic proliferation that diffusely infiltrates and focally effaces the brain parenchyma. The neoplasm has nuclear anaplasia, frequent multinucleated cells, mitoses, and microvascular cellular proliferation.

Special stains to better characterize the neoplasm are being requested and will be reported as an addendum.

=====

PROCEDURES/ADDENDA

Immunohistology

Interpretation

Brain, immunohistochemistry: MIB-1 proliferation index 28%

See Results and Comment.

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP depicts sparse gliofibrillogenesis by the neoplastic cells. The synaptophysin and NFP demonstrate a tenuous positive background, indicating the infiltrative character of the neoplasm. The Neu N demonstrates few small neurons entrapped by the neoplasm. More than 50% of the neoplastic cells over express the p53 protein, and about 28% of the cells are in the mitotic cycle as depicted by the MIB-1.

[page 2 of 2]
Comment: The immunophenotype is that of a high histological grade (WHO IV/IV) glial neoplasm, i.e. a glioblastoma.

INTRA-OPERATIVE CONSULTATION

A. Brain tumor, imprints and smears: Glioblastoma.

GROSS DESCRIPTION

A. Received fresh, several fragments, 0.6 cm. in aggregate. Semi firm, tannish-yellow and glistening. In total, A1-A2.

B.

SPECIMEN: Brain tumor permanent.

FIXATIVE: Formalin.

GENERAL: A 1.4 x 1.0 x 0.8 cm, 0.32 gm aggregate of several irregularly shaped red-gray-tan fragments.

SECTIONS: B1 all submitted.

ICD-9(s):

191.2 191.2

Histo Data

Part A: Brain tumor

Taken:	Received:
Stain/cnt	Block Ordered Comment
ChromA-DA x 1	1
mGFAP-DA x 1	1
H/E x 1	1
MIB1-DA x 1	1
NF2F11 x 1	1
P53DO7 x 1	1
Synap-DA x 1	1
H/E x 1	2

Part B: Brain tumor

Taken:	Received:
Stain/cnt	Block Ordered Comment
ChromA-DA x 1	1
H/E x 1	1
NF2F11 x 1	1
Synap-DA x 1	1

*** End of Report ***

Source: NCI Genomic Data Commons file cd496968-f431-438b-8d84-adb0be0be251 (TCGA-06-0237.29763612-8827-45E2-90C1-C69E0D5B18CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).